Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A632, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A632-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology

Hospital #

Gender: M

Location: [REDACTED]

Received: [REDACTED]

SURGICAL PATHOLOGY REPORT

ACCESSION NO.

Final Diagnosis(es):

(A) Prostate with seminal vesicles, excision:

- 1) Prostatic adenocarcinoma, Gleason grade 4+5.
- 2) Perineural invasion present.
- 3) Extracapsular penetration on right (Slide A1, A10, A11, A24, and A41)
- 4) Total tumor volume approximately 4.5 x 2.0 x 3.0 cm = 27 cc.
- 5) Pathologic stage: pT3aNOMX.
- 6) All surgical margins negative (see synoptic report).

(B) Bilateral pelvic lymph nodes, excision: Five lymph nodes, negative for metastasis.

Synoptic Report:

Diagnosis: Prostatic adenocarcinoma.

Procedure: Radical prostatectomy.

Specimen Size: 5.0 x 6.5 x 5.0 cm.

Specimen Weight: 78.1 gm.

Lymph Node Sampling: Pelvic lymph node dissection.

Histologic Type: Adenocarcinoma, acinar type.

Histologic Grade (Gleason pattern)

Primary Pattern: Grade 4

Secondary Pattern: Grade 5

Total Gleason Score: 9

Percent of Prostate Involved: 25%

Size of Dominant Nodule

Greatest dimension: 45 mm

Additional dimensions: 30 mm

Extraprostatic Extension: Nonfocal.

Seminal Vesicle Invasion:

Left: Not identified

Right: Not identified

Lymphovascular Invasion: Present.

Perineural Invasion: Present.

Periprostatic Fat Invasion: Present.

Margins:

Apical: Negative

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Bladder neck: Negative
Anterior: Negative
Lateral: Negative
Posterolateral: Negative
Posterior: Negative

Nodes: Node Group: Bilateral pelvic nodes

Total: 5

Positive: 0

Pathologic Stage: pT3apN0pMX.

[REDACTED]

Electronically Signed

Specimen(s) Received:

A: prostate with seminal vesicles

B: bilateral pelvic lymph nodes

Clinical History:

Prostate cancer. Tumor Bank.

[REDACTED]

Gross Description:

(A) (prostate with seminal vesicles) Received in formalin is a 78.1 gm, previously incised and inked prostate measuring 5.0 cm from base to apex, 6.5 cm right to left, and 5.0 cm superior to inferior. Attached seminal vesicles measure 6.0 cm in length, 4.0 cm right to left, and 1.5 cm in maximum thickness. Sectioning of the prostate reveals multiple cystic spaces ranging in diameter from 0.3 to 0.6 cm which could be native or introduced by tumor banking. Firm nodularity is centered in the right apex region, but vague nodularity persists throughout the sectioned prostate. Near the right base there is a 1.4 cm circular, dark black, gray, firm nodule. The apex most slice is removed and is serially longitudinally sectioned and submitted from right to left in cassettes A1-A9. The remaining body of the prostate is sectioned and submitted according to the University protocol in its entirety in cassettes A10-A52. The right seminal vesicle is serially sectioned and submitted sequentially in cassettes A53-A60. The left seminal vesicle is similarly sectioned and submitted serially from A61-A68.

(B) (bilateral pelvic lymph nodes) Received in formalin is a mass of adipose tissue with embedded candidate lymph nodes measuring 11.0 x 7.0 x 3.0 cm. Dissection reveals one large node that is submitted entirely in cassette B1. One large node is bisected and submitted in cassette B2. One large lymph node is serially sectioned and submitted in cassettes B3 and B4. One lymph node is bisected and submitted in cassette B5. One large lymph node is serially sectioned and submitted entirely in cassette B6.

[REDACTED]

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IHC antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology. They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EGFR(3C6), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26), Ki67(30-9).

Unless otherwise stated in the report, all tissue tested for HER2 by IHC and/or HER2 by FISH have been fixed as per C.A.P. requirements for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Hx: AA Discrepancy		✓

Final Report:
Printed:

Source: NCI Genomic Data Commons file b503d12b-ea56-411a-ad8a-a7c168f62796 (TCGA-HC-A632.9EF1E09B-C468-4A42-917E-365F88055077.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).